National Lung Screening Trial (NLST) participant 210497 — screening results, CT findings and lung cancer
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 69 years; Gender: male; Race: White; Cigarette smoking status at randomisation: current smoker; Enrolled through an American College of Radiology Imaging Network (ACRIN) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 11): Positive, change unspecified: nodule(s) >= 4 mm or enlarging nodule(s), mass(es), or other non-specific abnormalities suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 40 effective mAs, display field of view 34 cm, reconstruction filter Siemens B50F / Siemens B30.
- T1: No screening result: Not Expected - Cancer before screening window.
- T2: No screening result: Not Expected - Cancer before screening window.

Abnormalities recorded by the reading radiologist on the CT screens (3 abnormalities; numbered within each screening year; size, margins, attenuation and location were collected only for non-calcified nodules or masses of at least 4 mm; interval-change items come from the comparison read)
- T0 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left upper lobe; longest diameter 19 mm, longest perpendicular diameter 19 mm; margins spiculated (stellate); predominant attenuation other; greatest diameter on CT slice 95; pre-existing on earlier images (earliest visible 19 days before randomisation); interval growth could not be determined; change in attenuation could not be determined.
- T0 abnormality 2: Significant cardiovascular abnormality.
- T0 abnormality 3: Emphysema.

Lung cancer (1 primary lung cancer record; the first confirmed lung cancer followed a positive screen; study year of the first confirmed lung cancer: T0; the diagnosis is linked to a positive screen through the trial's diagnostic-procedure linking algorithm)
1. First primary lung cancer, diagnosed day 213, study year T0. Site: lower lobe of lung (ICD-O-3 C34.3). Primary tumour location: left lower lobe. Histology: non-small cell carcinoma (ICD-O-3 8046/3). Tumour size on pathology: 20 mm. AJCC 6th edition staging: stage IIIA (best stage, from clinical TNM); clinical T1 N2 M0 (stage IIIA); pathologic TX NX MX. AJCC 7th edition staging: stage IIIA; clinical T1a N2 M0; pathologic TX NX MX. Summary stage: regional.

Follow-up
Last known free of lung cancer: day 213 (for ACRIN participants with lung cancer this field holds the diagnosis date).
